Gene-level copy-number profile of tumor specimen TCGA-AG-3898-01A from TCGA case TCGA-AG-3898, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.6 years (22,492 days).
Specimen TCGA-AG-3898-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.862209bd-191e-42a7-8c33-38dbc024d0bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3898-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93509015-9b5c-4fc0-a72c-ddb3e414825c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 2,299; copy number 3: 12,963; copy number 4: 31,318; copy number 5: 9,057; copy number 6: 3,106; copy number 7: 189; copy number 8: 141; copy number 10: 134; copy number 13: 469; copy number 15: 74; copy number 18: 23; copy number 47: 5; copy number 65: 25; copy number 70: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3898-01A-01D-1428-01): tumor purity 0.53, ploidy 4.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr16:6,380,476–6,577,359, 2 genes: AC006112.1, AC007223.1.
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 734 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:38,530,031–38,704,747, 5 genes, copy number 47: SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6.
- chr17:39,027,277–39,747,291, 29 genes, copy number 65–70 (within-gene range 58–70): LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr20:15,552,157–45,746,287, 700 genes, copy number 10–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
